Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4188, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4188-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Cardia. Tumor configuration: Ulcerating. Tumor size: 8 x 5 x 1 cm. Histologic type: Signet ring cell carcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Not specified. Lymph nodes: 2 of 8 positive for metastasis. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file df844053-0172-40f4-b3cc-d3c636c443f9 (TCGA-BR-4188.03108A9A-1F00-48A4-86AB-81045EB07340.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).